Somatic mutation profile of tumor specimen MBCProject_5548_T1_WES (aliquot MBCProject_5548_T1_WES_1) from CMI case MBCProject_5548, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 68.6 years (25,039 days).
Specimen MBCProject_5548_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7c51f96-f3bb-4271-96d4-d9af1fc37792.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_5548_SALIVA (Saliva), aliquot MBCProject_5548_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da230e14-0ff2-47de-8d42-22f302b29f5d

The open-access MAF lists 57 somatic variants for this specimen: 39 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 9, Nonsense Mutation 4, Intron 4, RNA 3, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 13/131 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ARID1A | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 32/542 reads (6%) | catalogued as COSV61371604, COSV61372723; called by muse, mutect2
- CAPN6 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 65/632 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60694606; called by muse, mutect2, varscan2
- CDH1 | c.2002A>T p.K668* | Nonsense Mutation (SNP) | VAF 57/440 reads (13%) | catalogued as COSV55728400, COSV55745326; called by muse, mutect2, varscan2
- COLEC11 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as rs769978108, COSV52592400; called by muse, mutect2
- DLC1 | c.638C>A p.T213N | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV52310318, COSV99364783; called by muse, mutect2, varscan2
- DPYSL4 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1229373997, COSV100633846, COSV104406378; called by muse, mutect2
- FLG | c.2245G>A p.D749N | Missense Mutation (SNP) | VAF 43/606 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as rs779930090; called by muse, mutect2
- JCAD | c.3809G>A p.R1270Q | Missense Mutation (SNP) | VAF 28/427 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.865); catalogued as rs373376609, COSV100948067; called by muse, mutect2
- KIF16B | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755037043, COSV61702209; called by muse, mutect2
- LCN12 | c.456C>G p.S152R | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as rs1488701841; called by mutect2, varscan2
- MAB21L2 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58263143; called by muse, mutect2
- NUDT19 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs773320719; called by muse, mutect2
- PARP2 | c.1709G>C p.R570P | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51640109; called by muse, mutect2, varscan2
- PLB1 | c.1013G>A p.S338N | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59823458; called by muse, mutect2, varscan2
- SETX | c.3994C>T p.Q1332* | Nonsense Mutation (SNP) | VAF 21/172 reads (12%) | catalogued as COSV56392343; called by muse, mutect2, varscan2
- SPEG | c.8141G>A p.R2714Q | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs772920788; called by muse, mutect2
- SPTAN1 | c.5903G>C p.R1968T | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1319330428; called by muse, mutect2
- TBX3 | c.367A>G p.M123V | Missense Mutation (SNP) | VAF 45/452 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57469719, COSV99050626; called by muse, mutect2, varscan2
- TENM2 | c.2588T>C p.L863S (on ENST00000518659 / NM_001122679.2; = p.L631S on NM_001080428.3) | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV69131795; called by muse, mutect2
- TPCN2 | c.1772A>G p.Y591C | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs561059890; called by muse, mutect2
- USP2 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV52733031; called by muse, mutect2
- BMS1 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 27/385 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.028); called by muse, mutect2
- COL11A1 | c.4462G>C p.G1488R | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.326); called by muse, mutect2
- DNAH12 | c.4121G>A p.R1374K (on ENST00000351747; = p.R1397K on NM_001366028.2) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, varscan2
- FKBPL | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.15); called by muse, mutect2
- GZF1 | c.1494G>C p.K498N | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HMCN1 | c.12793C>A p.L4265I | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- NIPSNAP1 | c.451T>C p.F151L | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.04); called by muse, mutect2
- NOCT | c.884G>C p.R295P | Missense Mutation (SNP) | VAF 39/358 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- NUDT15 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PRSS21 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 58/360 reads (16%) | called by muse, mutect2, varscan2
- PSME4 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SSH2 | c.2999C>T p.A1000V | Missense Mutation (SNP) | VAF 55/308 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUPT16H | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- TAF1 | c.5537G>A p.S1846N (on ENST00000373790 / NM_138923.4; = p.S1867N on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- TP53BP1 | c.2593G>C p.E865Q | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.024); called by muse, mutect2
- WDFY4 | c.9020T>A p.I3007N | Missense Mutation (SNP) | VAF 70/320 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by mutect2, varscan2
- ZFHX2 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); called by muse, mutect2
- ACACA | c.4240C>T p.L1414= | Silent (SNP) | VAF 36/476 reads (8%) | catalogued as rs148729289; called by muse, mutect2
- CDH17 | c.2427C>T p.R809= | Silent (SNP) | VAF 15/219 reads (7%) | called by muse, mutect2
- LLGL2 | c.3045C>T p.S1015= (on ENST00000392550 / NM_001031803.2; = p.A1001V on NM_004524.3) | Silent (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- PARP14 | c.2805G>A p.E935= | Silent (SNP) | VAF 24/404 reads (6%) | called by muse, mutect2
- PCDHB16 | c.1782C>T p.G594= | Silent (SNP) | VAF 45/337 reads (13%) | catalogued as rs782295919, COSV53358832; called by muse, mutect2, varscan2
- RHOC | c.581G>A p.*194= | Silent (SNP) | VAF 28/502 reads (6%) | called by muse, mutect2
- SIRPG | c.633C>T p.A211= | Silent (SNP) | VAF 40/379 reads (11%) | catalogued as rs369342332; called by muse, mutect2, varscan2
- TAS2R8 | c.738A>G p.L246= | Silent (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- ZNF280A | c.1344G>A p.R448= | Silent (SNP) | VAF 16/260 reads (6%) | called by muse, mutect2
- AC024940.1 | n.2830G>A | RNA (SNP) | VAF 52/520 reads (10%) | catalogued as rs755238702; called by muse, mutect2, varscan2
- C11orf49 | c.46+11266C>G | Intron (SNP) | VAF 30/464 reads (6%) | called by muse, mutect2
- CACFD1 | c.-4C>G | 5'UTR (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2
- DIAPH3 | c.2737+107C>T | Intron (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- GANC | c.-85G>C | 5'UTR (SNP) | VAF 11/305 reads (4%) | called by muse, mutect2
- HMGCLL1 | c.632+24C>G | Intron (SNP) | VAF 10/136 reads (7%) | catalogued as COSV99231409; called by muse, mutect2
- LINC01164 | n.861C>T | RNA (SNP) | VAF 34/423 reads (8%) | catalogued as rs1378379775; called by muse, mutect2
- PLAU | c.57+20G>C | Intron (SNP) | VAF 25/244 reads (10%) | catalogued as COSV101032418; called by muse, mutect2, varscan2
- TRBV21OR9-2 | n.236G>T | RNA (SNP) | VAF 21/228 reads (9%) | called by muse, mutect2
